CCDI case PBCFEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/fac3006a-63dc-440b-af8d-c0d3262ba43b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.2 years (90 days).

Biospecimens (2 samples)
- Sample 0DVZ0V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ19: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
